Somatic mutation profile of tumor specimen TCGA-AN-A0AS-01A (aliquot TCGA-AN-A0AS-01A-11W-A019-09) from TCGA case TCGA-AN-A0AS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.2 years (25,658 days).
Specimen TCGA-AN-A0AS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74540e1e-3e53-4965-9565-dc25eff97482.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0AS-10A (Blood Derived Normal), aliquot TCGA-AN-A0AS-10A-01W-A021-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37488d16-6467-43de-805e-ef308bbf2031

The open-access MAF lists 38 somatic variants for this specimen: 33 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 26, Silent 5, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.55810C>T p.R18604* (on ENST00000591111; = p.R11180* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 39/227 reads (17%) | catalogued as rs1057522256, COSV100593106, COSV60332406; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADD3 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1441828066, COSV53323803; called by muse, mutect2, varscan2
- AGPAT3 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs774081698, COSV52373155; called by muse, mutect2
- AKAP4 | c.1918G>C p.E640Q | Missense Mutation (SNP) | VAF 61/498 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV62075422; called by muse, mutect2, varscan2
- AL133500.1 | c.1583T>C p.L528P | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.15); catalogued as COSV55745194; called by muse, mutect2, varscan2
- AOX1 | c.1534G>C p.V512L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV65983872; called by muse, mutect2, varscan2
- BAZ1B | c.1476G>T p.R492S | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV59994467; called by muse, mutect2, varscan2
- CFH | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs140107330; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- CHD2 | c.2855A>G p.E952G | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV101245675; called by muse, mutect2, varscan2
- COL22A1 | c.3151-1G>T p.X1051_splice | Splice Site (SNP) | VAF 45/178 reads (25%) | catalogued as COSV57336752; called by muse, mutect2, varscan2
- EPAS1 | c.625A>G p.N209D | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV55390169; called by muse, mutect2, varscan2
- FAM47B | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 133/342 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs779258509, COSV61456680; called by muse, mutect2, varscan2
- FLG2 | c.6715C>T p.Q2239* | Nonsense Mutation (SNP) | VAF 50/1024 reads (5%) | catalogued as COSV101166042; called by muse, mutect2
- FREM2 | c.8342G>A p.R2781H | Missense Mutation (SNP) | VAF 95/539 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs756570666, COSV54841703; called by muse, mutect2, varscan2
- GPR156 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 48/254 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as rs150101992; called by muse, mutect2, varscan2
- IGHG1 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 36/380 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs587725593; called by muse, varscan2
- KCNH4 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); catalogued as rs138796695; called by muse, mutect2, varscan2
- LHX9 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV61331411; called by muse, mutect2, varscan2
- MADD | c.1705+1G>T p.X569_splice | Splice Site (SNP) | VAF 30/104 reads (29%) | catalogued as COSV60629562; called by muse, mutect2, varscan2
- OR14C36 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs1558292883, COSV58601900; called by muse, mutect2, varscan2
- PCDHA6 | c.1855C>T p.R619C | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs1554132419, COSV65346430; called by muse, mutect2
- RAD17 | c.1496C>T p.T499M (on ENST00000380774 / NM_133339.2; = p.T488M on NM_002873.1) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1251489482, COSV51459519; called by muse, mutect2, varscan2
- TAF1 | c.4051C>T p.H1351Y (on ENST00000373790 / NM_138923.4; = p.H1372Y on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.299); catalogued as COSV52124391; called by muse, mutect2, varscan2
- TEAD2 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV60875034; called by muse, mutect2, varscan2
- TGFA | c.73A>G p.N25D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV54916231; called by muse, mutect2, varscan2
- TIMELESS | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 46/337 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57515043; called by muse, mutect2, varscan2
- TMEM44 | c.1150G>C p.V384L (on ENST00000392432 / NM_001166305.2; = p.V337L on NM_138399.5) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV56448031, COSV56451298, COSV56451764; called by muse, mutect2, varscan2
- TTC8 | c.797C>T p.S266L (on ENST00000338104 / NM_001288781.1; = p.S250L on NM_144596.4) | Missense Mutation (SNP) | VAF 17/475 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs943156593, COSV100581538; called by muse, mutect2
- TTLL8 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV56723961, COSV99838506; called by muse, mutect2
- ZNF711 | c.1028G>A p.C343Y | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as COSV52158744; called by muse, mutect2, varscan2
- MAP3K1 | c.1762dup p.S588Ffs*3 | Frame Shift Ins (INS) | VAF 83/192 reads (43%) | called by mutect2, pindel, varscan2
- SPIDR | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 62/732 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- TP53 | c.329_331del p.R110del | In Frame Del (DEL) | VAF 110/230 reads (48%) | called by mutect2, pindel, varscan2
- COL4A5 | c.1140T>C p.G380= | Silent (SNP) | VAF 94/545 reads (17%) | catalogued as COSV60371511; called by muse, mutect2, varscan2
- RYR3 | c.3303C>T p.V1101= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs752550511, COSV66801263, COSV66810148; ClinVar: likely benign; called by muse, mutect2, varscan2
- TCF21 | c.246C>T p.N82= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV52818210; called by muse, mutect2
- TDRP | c.237G>A p.E79= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as rs1290570602; called by muse, mutect2
- WRNIP1 | c.1812G>A p.L604= | Silent (SNP) | VAF 34/101 reads (34%) | catalogued as COSV66356414; called by muse, mutect2, varscan2
